Somatic mutation profile of tumor specimen 0DUME6 from CCDI case PBCLIT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.1 years (4,767 days).
Specimen 0DUME6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9839d39b-3ca9-4390-9d70-0a664541e3c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUMDP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/455489ee-4027-4b11-995e-2814bd56ed6f

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Splice Region 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 50/994 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CRYBG2 | c.4123G>T p.D1375Y | Missense Mutation (SNP) | VAF 183/549 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- POU5F2 | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 83/758 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- VPS41 | c.1740T>A p.I580= | Splice Region (SNP) | VAF 33/1179 reads (3%) | called by muse, mutect2
- MBD3L3 | c.420G>A p.E140= | Silent (SNP) | VAF 34/194 reads (18%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 58/1106 reads (5%) | called by muse, mutect2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 9/167 reads (5%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 29/256 reads (11%) | called by muse, varscan2
